Gene-level copy-number profile of tumor specimen TCGA-73-7499-01A from TCGA case TCGA-73-7499, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 81.3 years (29,683 days).
Specimen TCGA-73-7499-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.5f2d5688-df45-46b2-aebf-2cd3c0b0e93a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-73-7499-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e81d2361-4bd6-4943-8f9a-1693d23ea44c

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 23,345; copy number 2: 17,864; copy number 3: 10,919; copy number 4: 5,827; copy number 5: 1,855.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-73-7499-01A-11D-2183-01): tumor purity 0.38, ploidy 3.22, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:145,872,209–146,145,217, 3 genes: AC079248.1, AC079248.2, RNU7-2P.
- chr9:77,456,295–77,526,697, 1 gene: GNA14-AS1.
- chr10:88,048,135–88,049,823, 1 gene: MED6P1.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 17,937 genes in 33 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–212,816,830, 1,827 genes, copy number 4–5 (within-gene range 2–5) (broad region; genes not listed).
- chr1:222,088,806–225,473,837, 65 genes, copy number 4 (within-gene range 2–4) (broad region; genes not listed).
- chr1:226,989,865–227,318,474, 1 gene, copy number 4 (within-gene range 2–4): CDC42BPA.
- chr1:227,123,895–232,041,272, 160 genes, copy number 4 (broad region; genes not listed).
- chr1:237,042,184–237,833,988, 1 gene, copy number 4 (within-gene range 2–4): RYR2.
- chr1:237,471,119–246,931,948, 161 genes, copy number 4 (within-gene range 2–4) (broad region; genes not listed).
- chr2:144,517,978–145,827,830, 17 genes, copy number 3: ZEB2-AS1, AC009951.2, AC009951.1, AC009951.3, AC009951.6, LINC01412, TEX41, AC023128.1, AC023128.2, SGCEP1, LINC01966, AC096666.1, RPL6P5, AC092484.1, AC079163.2, AC079163.1, METAP2P1.
- chr3:104,502,700–198,222,513, 1,659 genes, copy number 4 (broad region; genes not listed).
- chr5:58,198–44,066,731, 695 genes, copy number 5 (broad region; genes not listed).
- chr5:165,782,805–166,029,311, 3 genes, copy number 4: AC008562.1, AC008489.1, RPL7P20.
- chr5:167,284,799–168,264,157, 1 gene, copy number 4 (within-gene range 2–4): TENM2.
- chr5:167,653,228–168,667,761, 17 genes, copy number 4: AC008708.2, AC008708.1, AC008464.1, AC008705.2, AC008705.1, AC011369.1, AC011369.2, CTB-178M22.2, WWC1, RARS1, FBLL1, PANK3, SLC2A3P1, MIR103A1, MIR103B1, RPL10P9, AC011365.1.
- chr5:170,353,487–170,736,632, 1 gene, copy number 4 (within-gene range 2–4): KCNIP1.
- chr5:170,483,806–181,342,213, 325 genes, copy number 4 (broad region; genes not listed).
- chr6:167,607–62,611,327, 1,541 genes, copy number 3 (broad region; genes not listed).
- chr7:70,972–159,233,377, 3,014 genes, copy number 3–4 (broad region; genes not listed).
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 4 (broad region; genes not listed).
- chr9:60,914,407–73,170,393, 237 genes, copy number 3 (broad region; genes not listed).
- chr9:101,569,352–104,329,396, 20 genes, copy number 3: GRIN3A, PPP3R2, MTND3P4, ARL2BPP7, RNU6-329P, AL442644.2, AL442644.1, LINC00587, ZYG11AP1, AL365396.1, CYLC2, AL589823.1, LINC01492, AL390962.1, RNA5SP291, AL590381.1, SMC2-AS1, SMC2, TOPORSLP, AL512646.1.
- chr9:108,626,833–117,685,588, 150 genes, copy number 3–5 (broad region; genes not listed).
- chr9:117,704,175–117,724,735, 2 genes, copy number 3: TLR4, RNU6-1082P.
- chr9:118,687,752–138,203,325, 566 genes, copy number 3 (broad region; genes not listed).
- chr10:85,599,552–86,366,795, 1 gene, copy number 3 (within-gene range 2–3): GRID1.
- chr10:86,052,448–86,403,201, 4 genes, copy number 3: RNA5SP322, MIR346, AL844892.2, AL844892.1.
- chr12:21,797,401–21,942,529, 1 gene, copy number 4 (within-gene range 1–4): ABCC9.
- chr12:22,008,348–22,065,674, 2 genes, copy number 4: AC092862.1, CMAS.
- chr12:22,104,491–22,195,629, 3 genes, copy number 4: AC007671.1, SULT6B2P, RNU1-149P.
- chr12:123,575,891–132,956,304, 266 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).
- chr14:35,121,846–35,317,474, 2 genes, copy number 3 (within-gene range 1–3): PRORP, AL121594.1.
- chr14:35,157,904–106,875,071, 1,673 genes, copy number 3 (broad region; genes not listed).
- chr17:21,614,487–83,095,122, 2,155 genes, copy number 3–4 (within-gene range 1–4) (broad region; genes not listed).
- chr20:19,000,709–64,313,132, 1,088 genes, copy number 3–5 (broad region; genes not listed).
- chr21:10,328,411–46,665,124, 745 genes, copy number 3–5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 21,588. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
